Surgical pathology report (de-identified scan), TCGA case TCGA-76-6662, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Thomas Jefferson University, specimen TCGA-76-6662-01A (Primary Tumor).

[page 1 of 3]
ADDED

TCGA-76-6662

SURGICAL PATHOLOGY REPORT

FINAL DIAGNOSIS:

1. Right parietal brain mass: GLIOBLASTOMA, WHO GRADE IV.
2. Right parietal brain mass: GLIOBLASTOMA, WHO GRADE IV. SEE MICROSCOPIC DESCRIPTION.

This diagnostic report has been personally interpreted by the signatory of record.

Aperio

Ki67

Percent : 28%

Cells counted : 29,825 cells

This test was performed by IHC in conjunction with the Aperio-computer assisted image analysis.

Addendum

IMMUNOHISTOCHEMICAL STAIN

GFAP: POSITIVE STAINING OF TUMOR CELLS.

[page 2 of 3]
Microscopic Description:

The tumor is composed of pleomorphic glial cells. Mitotic figures are identified in tumor cells. Areas of tumor necrosis are present. An addendum with the results of immunohistochemical stains will be issued.

See synoptic below.

2. Right parietal brain mass:

History of Previous Tumor/Familial Syndrome: Not specified
Specimen Type/Procedure: Open biopsy
Specimen Handling: Unfrozen for routine permanent paraffin sections
Specimen Size: Greatest dimension: 2.0 cm
Additional dimension: 1.8 cm
Additional dimension: 0.5 cm
Laterality: Right
Tumor Site: Brain/cerebrum-Parietal
Histologic Type and Grade: Glioblastoma (WHO grade IV)
Histologic Grade: WHO Grade IV
Margins: Cannot be assessed
Ancillary Studies: Immunohistochemistry: GFAP, KI67

Frozen Section Diagnosis:

1. Right parietal brain mass: Malignant astrocytic neoplasm. More tissue requested if clinically indicated. . Frozen section diagnosis by [REDACTED]

Clinical History and Diagnosis:

Right parietal brain mass

Source of Specimen:

1: Right parietal brain mass
2: Right parietal brain mass

[REDACTED]

1. Right parietal brain mass: Received fresh for frozen analysis in a [REDACTED]

[page 3 of 3]
[REDACTED]

specimen container labeled with the patient's name and "#1 right parietal brain mass" is an aggregate of tan soft tissue measuring 0.5 x 0.4 x 0.2 cm. Touch preparations are prepared, and 100% of the tissue is submitted for frozen section. The specimen is entirely submitted in one cassette for permanent sectioning.

2. Right parietal brain mass: Received in formalin in a specimen container labeled with the patient's name and "#2 right parietal brain mass" are multiple fragments of tan-red tissue ranging in size from 0.1-2 cm and measuring 2 x 1.8 x 0.5 cm in aggregate. The specimen is entirely submitted in 2 cassettes.

Histology Laboratory
H&E

Part 2: Right parietal brain mass
GLIAL FIBRIILLARY ACIDIC PROTEIN (GFAP)
KI 67 (Aperio)

Immunohistochemistry Notes

1. Quantification of immunohistochemistry assay for ER and PR studies is by the method of Battiafora et.al. Applied Immunohistochemistry, [REDACTED]

2. Pathway Her-2/neu (4B5) (Rabbit monoclonal) - Formalin-fixed, paraffin embedded tissue. UltraView Universal Detection Kit. Interpretation follows the manufacturer's recommendation.

3. EGFR (3C6) (Mouse Monoclonal) Formalin-fixed, paraffin embedded tissue. UltraView Universal Detection Kit.

4. Analyte Specific Reagent (ASCR) Disclaimer. The use of one or more reagents in the above tests is regulated as an analyte specific reagent (ASR). These tests were developed and their performance characteristics determined by the Clinical Laboratory of [REDACTED]

[REDACTED]

They have not been cleared by the US Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary.

[REDACTED]

Source: NCI Genomic Data Commons file 3bede220-b68f-4e80-a4ce-f5a4caa41c6b (TCGA-76-6662.58DD362C-D11C-4B10-9B2B-40E3D2BA3192.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).